Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6995, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6995-01A (Primary Tumor).

[page 1 of 7]
Pathology Report [REDACTED] **FINAL**

Report Type Pathology Report

Date of Event [REDACTED]

Sex M

Authored by [REDACTED]

Hosp/Group [REDACTED]

Record Status FINAL

FINAL DIAGNOSIS:

PART 1: LEVEL 1A, DISSECTION

TWO BENIGN LYMPH NODES (0/2).

PART 2: DEEP MARGIN, BIOPSY

NO TUMOR SEEN.

PART 3: RIGHT MANDIBLE, COMPOSITE RESECTION

A. INVASIVE SQUAMOUS CELL CARCINOMA OF THE FLOOR OF MOUTH (6.5 CM), MODERATELY DIFFERENTIATED, KERATINIZING, INVOLVING MANDIBULAR BONE AND SKIN.

B. ANGIOLYMPHATIC INVASION IS PRESENT. PERINEURAL INVASION IS ABSENT.

C. ALL MUCOSAL, CUTANEOUS, AND BONY MARGINS ARE FREE OF CARCINOMA (ALSO SEE PARTS 2-10). CARCINOMA IS 0.4 CM FROM POSTERIOR SKIN MARGIN AND <0.1 CM FROM SUPERIOR BUCCAL SOFT TISSUE MARGIN.

D. ONE BENIGN LYMPH NODE (0/1).

E. SUBMANDIBULAR GLAND WITH NO SIGNIFICANT PATHOLOGIC ABNORMALITIES.

F. PATHOLOGIC STAGE: pT4a N0.

PART 4: RIGHT FLOOR OF MOUTH MARGIN, BIOPSY

NO TUMOR SEEN.

PART 5: LEFT FLOOR OF MOUTH MARGIN, BIOPSY

NO TUMOR SEEN.

PART 6: RIGHT RETROMOLAR TRIGONE MARGIN, BIOPSY

NO TUMOR SEEN.

PART 7: RIGHT BUCCAL MARGIN, BIOPSY

SQUAMOUS MUCOSA WITH KERATOSIS, NO TUMOR SEEN.

PART 8: SUBLABIAL MARGIN, BIOPSY

NO TUMOR PRESENT.

PART 9: ANTERIOR MANDIBULAR MARROW, BIOPSY

NO TUMOR SEEN.

PART 10: POSTERIOR MANDIBULAR MARROW, BIOPSY

NO TUMOR SEEN.

PART 11: RIGHT NECK, LEVELS 2-4, DISSECTION

A. TWENTY-NINE BENIGN LYMPH NODES (0/29).

B. MINUTE FRAGMENTS OF SALIVARY TISSUE WITH CHRONIC SIALADENITIS.

PART 12: LEFT LEVELS 1-4, DISSECTION

A. NINETEEN BENIGN LYMPH NODES (0/19).

B. SUBMANDIBULAR GLAND WITH NO SIGNIFICANT PATHOLOGIC ABNORMALITIES.

[REDACTED]
[REDACTED]
Pathologist: [REDACTED]

** Report Electronically Signed Out **

By Pathologist: [REDACTED]
[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

[page 2 of 7]
The specimen is received in twelve parts.

Part 1 is received fixed labeled with the patient's name, initials XXX and "level 1A". It consists of a tan-yellow fibroadipose specimen measuring 4.3 x 3.2 x 1.2 cm. Multiple possible lymph nodes are identified ranging in greatest dimension from 0.3 cm to 1.2 cm and are submitted as follows:

1A one lymph node, bisected

1B possible lymph nodes.

Part 2 is received fixed labeled with the patient's name, initials XXX and "deep margin". It consists of four fragments of tan-yellow adipose tissue and tan connective tissue measuring in aggregate 4.0 x 2.7 x 0.8 cm. The specimen is entirely submitted in cassettes 2A-2C.

Part 3 is received fixed labeled with the patient's name, initials XXX and "right composite resection". It consists of a right hemimandibulectomy measuring 11.0 x 7.5 x 6.0 cm with attached skin measuring 4.5 x 4.0 cm and submandibular gland measuring 4.5 x 2.5 x 2.0 cm. Grossly there is a 6.5 x 5.0 x 4.0 cm tan-white ulcerated tumor involving the soft tissue and underlying mandible. The lesion is serially cross sectioned revealing an involvement of the overlying skin. The tumor lies within 0.5 cm from the posterior skin margin, 1.0 cm from the inferior skin margin, 1.3 cm from the anterior skin margin, and 1.2 cm from the superior skin margin. The submandibular gland is serially cross sectioned revealing tan, homogenous lobular unremarkable parenchyma. One lymph node is identified measuring 1.2 x 1.0 x 0.5 cm.

Ink Code:

Black all margins

Blue area superseded by part 2 (deep margin)

Cassette Code:

3A anterior mucosal edge, shave

3B buccal mucosal edge, shave

3C retromolar trigone mucosal edge, shave

3D floor of mouth mucosal edge, shave

3E posterior skin margin, perpendicular

3F superior cheek, soft tissue margin, perpendicular

3G superior posterior soft tissue edge (blue ink), perpendicular

3H tumor involving dermis

3I superior mandibular bone margin, shave

3J anterior mandibular bone margin, shave

3K-3M representative of tumor

3N tumor relative to bone

3O representative of submandibular gland

3P one lymph node.

Part 4 is received fixed labeled with the patient's name, initials XXX and "right floor of mouth margin". It consists of tan connective tissue covered with gray-white mucosa. A clip marks anterior margin which is inked black. After frozen section analysis the specimen is submitted in cassette 4AFS.

Part 5 is received fixed labeled with the patient's name, initials XXX and "left floor of mouth margin". It consists of tan connective tissue covered with gray-white mucosa. A clip marks anterior margin which is inked black. After frozen section analysis the specimen is submitted in cassettes 5AFS.

Part 6 is received fixed labeled with the patient's name, initials XXX and "right retromolar trigone margin". It consists of tan connective tissue covered with gray-white mucosa. A clip marks superior margin which is inked black. After frozen section analysis the specimen is submitted in cassette 6AFS.

Part 7 is received fixed labeled with the patient's name, initials XXX and "right buccal margin". It consists of tan connective tissue with no mucosa. A

[page 3 of 7]
clip marks anterior margin which is inked black. After frozen section analysis the specimen is submitted in cassette 7AFS.

Part 8 is received fixed labeled with the patient's name, initials XXX and "sublabial margin". It consists of tan connective tissue covered with gray-white mucosa. A clip marks anterior margin which is inked black. After frozen section analysis the specimen is submitted in cassette 8AFS.

Part 9 is received fixed labeled with the patient's name, initials XXX and "anterior mandibular marrow". It consists of tan connective tissue fragments. After frozen section analysis the specimen is submitted in cassette 9AFS.

Part 10 is received fixed labeled with the patient's name, initials XXX and "posterior mandibular marrow". It consists of a tan connective tissue fragments. After frozen section analysis the specimen is submitted in cassettes 10AFS.

Part 11 is received fixed labeled with the patient's name, initials XXX and "right neck levels 2-4". It consists of a tan-yellow elongated fibroadipose tissue measuring 17.0 x 6.8 x 1.0 cm. The specimen is divided into three parts A, B, and C. Multiple possible lymph nodes are identified ranging in greatest dimension from 0.2 to 2.6 cm in part A. The largest lymph node is serially cross sectioned revealing possible metastasis. Multiple possible lymph nodes are identified in greatest dimension from 0.2 to 1.5 cm in part B. Multiple possible lymph nodes are identified in greatest dimension from 0.1 to 0.7 cm in part C.

Cassette:

11A representative of largest lymph node, part A

11B one lymph node, bisected, part A

11C three possible lymph nodes, part A

11D six possible lymph nodes, part A

11E one lymph node, bisected, part B

11F through 11G possible lymph nodes, part B

11H through 11I possible lymph nodes, part C.

Part 12 is received fixed labeled with the patient's name, initials XXX and "left levels 1, 2, 3, and 4". It consists of tan-yellow, elongated fibroadipose specimen measuring 15.0 x 7.0 x 2.0 cm. A submandibular gland measuring 4.5 x 2.0 x 1.5 cm is identified. Multiple possible lymph nodes are identified ranging in greatest dimension from 1.0 to 1.6 cm in level A. Multiple possible lymph nodes are identified ranging in greatest dimension from 0.2 to 1.3 cm in level 3. Multiple possible lymph nodes are identified ranging in greatest dimension from 0.2 to 2.5 cm in level 4.

Cassette code:

12A representative of submandibular gland

12B one lymph node, bisected, level 1

12C three lymph nodes, level 1

12D four possible lymph nodes, level 3

12E possible lymph nodes, level 3

12F one lymph node, level 4

12G one lymph node, bisected, level 4

12H possible lymph nodes, level 4.

Dictated by [REDACTED]

INTRAOPERATIVE CONSULTATION:

4AFS: RIGHT FLOOR OF MOUTH MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES.

B. BENIGN.

C. NO TUMOR PRESENT. [REDACTED]

5AFS: LEFT FLOOR OF MOUTH MARGIN (frozen section)

[page 4 of 7]
- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR PRESENT. ([REDACTED]),

6AFS: RIGHT RETROMOLAR TRIGONE MARGIN (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR PRESENT. ([REDACTED]),

7AFS: RIGHT BUCCAL MARGIN (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR PRESENT.
- D. KERATOSIS. ([REDACTED])

8AFS: SUBLABIAL MARGIN (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR PRESENT. ([REDACTED]),

9AFS: ANTERIOR MANDIBULAR MARROW (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR PRESENT. ([REDACTED]),

10AFS: POSTERIOR MANDIBULAR MARROW (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR PRESENT. ([REDACTED])

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: Right composite mandibulectomy

TUMOR SITE: Oral Cavity

TUMOR SIZE: Greatest dimension: 6.5 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PRIMARY TUMOR (pT): pT4a

[page 5 of 7]
REGIONAL LYMPH NODES (pN): pN0
Number of regional lymph nodes examined: 51
Number of regional lymph nodes involved: 0
DISTANT METASTASIS (pM): pMX
MARGINS: Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):
Present
PERINEURAL INVASION: Absent

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Mouth carcinoma.

PROCEDURE: Neck dissection.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

██████████

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Lymph Node, Level 1A

Taken: ██████████ Received: ██████████

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

Part 2: Deep Margins

Taken: ██████████ Received: ██████████

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

Part 3: Neck Dissection, Right Composite

Taken: ██████████ Received: ██████████

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 K

H&E x 1 L

H&E x 1 M

H&E x 1 O

H&E x 1 P

H&E x 1 Q

H&E x 1 R

H&E x 1 S

H&E x 1 IDR

H&E x 1 JDR

H&E x 1 NDR

[page 6 of 7]
Part 4: Right Floor of Mouth

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 5: Left Floor of Mouth

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 6: Right Retromolar

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 7: Right Buccal Biopsy

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 8: Sub Labial

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 9: Anterior Mandiblar Marrow

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 10: Posterior Mandibular Marrow

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 11: Left Lymph Node, Levels 2-4

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 I

H&E x 1 J

Part 12: Left Lymph Node, Level 1, 2, 3, 4

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 I

H&E x 1 J

TC1

Source: NCI Genomic Data Commons file 66439abc-1964-4963-bcff-b72ed1b043b8 (TCGA-CN-6995.2BBCB266-75F2-4F85-A251-3E6A2A020293.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).